FM case AD5024 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/380379ab-68c9-4230-8a1e-8d91b2a04d4d

Female, 49.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
